Somatic mutation profile of tumor specimen 0DWGJG from CCDI case PBCLRT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.0 years (731 days).
Specimen 0DWGJG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2213e7f-2dae-40a3-834b-39194f889f5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWGIZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6117c5bf-aa03-4bf4-95d0-9ec51dda2422

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP13A4 | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 233/500 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs748130648; called by muse, mutect2, varscan2
- CPXM2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 40/495 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs376038492; called by muse, mutect2
- PLEKHA4 | c.1623del p.R542Gfs*14 | Frame Shift Del (DEL) | VAF 128/328 reads (39%) | catalogued as COSV99613268; called by mutect2, pindel, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- REEP4 | c.418-47C>A | Intron (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- TMEM248 | c.*91A>T | 3'UTR (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
